Somatic mutation profile of tumor specimen 0DVXFH from CCDI case PBCKSU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.7 years (6,455 days).
Specimen 0DVXFH: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 055981e8-c213-4d65-97bd-cd262edc02e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d77f580-576e-4454-beb5-ff4b8666760d

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 4, Silent 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 183/445 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BAHCC1 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 133/325 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs1555653303; called by muse, mutect2, varscan2
- NXPH2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 17/526 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207058572; called by muse, mutect2
- MCM2 | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTF | c.1521T>C p.Y507= | Silent (SNP) | VAF 153/445 reads (34%) | called by muse, mutect2, varscan2
- CD164 | c.176-14C>T | Intron (SNP) | VAF 119/225 reads (53%) | catalogued as rs771811963; called by muse, mutect2, varscan2
- FBLN1 | c.80-28C>T | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs200607673; called by mutect2, varscan2
- OR14J1 | c.*10C>A | 3'UTR (SNP) | VAF 160/453 reads (35%) | called by muse, mutect2, varscan2
- PROSER1 | c.112-28del | Intron (DEL) | VAF 96/281 reads (34%) | called by mutect2, pindel, varscan2
- STARD8 | c.-167C>A | 5'UTR (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- TKFC | c.983-32C>T | Intron (SNP) | VAF 30/316 reads (9%) | catalogued as rs766975462; called by muse, mutect2
